Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6324, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6324-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. EXCISIONAL BX RIGHT GROIN NODE
- B. LEFT TUBE AND OVARY
- C. RIGHT OVARIAN CYST
- D. MESENTERIC MASS

CGA - G8 - 6324

DIAGNOSIS:

- A. RIGHT GROIN LYMPH NODE, EXCISION:
- DIFFUSE LARGE B CELL LYMPHOMA (SEE NOTE)
- B. LEFT FALLOPIAN TUBE AND OVARY, LEFT SALPINGO-OOPHORECTOMY:
- BENIGN FALLOPIAN TUBE AND OVARY
- C. RIGHT OVARIAN CYST, EXCISION:
- CORPUS LUTEUM CYST
- D. MESENTERIC MASS, BIOPSY:
- DIFFUSE LARGE B CELL LYMPHOMA (SEE NOTE)

NOTE: This lymphoma exhibits a non-germinal-center-like immunophenotype

See MICROSCOPIC DESCRIPTION

SPECIMEN(S):

- A. EXCISIONAL BX RIGHT GROIN NODE B. LEFT TUBE AND OVARY C. RIGHT OVARIAN CYST D. MESENTERIC MASS

CLINICAL HISTORY:

Abdominal mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA. Right groin lymph node: No carcinoma seen. Atypical lymphoid hyperplasia (additional lymph node tissue is requested, if possible, for lymphoma workup).
FSB. Left fallopian tube and ovary: (Grossly and in one section of the ovary) No tumor seen.
FSD. Mesenteric mass (touch preparation only): Suspicious for lymphoma; lymphoma work up is requested. By

GROSS DESCRIPTION:

- A. RIGHT GROIN LYMPH NODE EXCISIONAL BIOPSY
Received fresh is a 3 x 2 x 1 cm. fragment of tan-yellow adipose tissue containing a 0.7 x 0.6 x 0.5 cm. The entire lymph node is submitted for frozen section in FSA1.
- B. LEFT FALLOPIAN TUBE AND OVARY:
Received fresh is a 6 x 0.4 cm fallopian tube and 5.5 x 4.0 x 1.9 cm ovary. They are grossly negative for tumor. Sections are submitted in FSB1 (frozen section of ovary representative) and B2 to B6.
- C. RIGHT OVARIAN CYST
Received in formalin are two tissue fragments aggregating to 3.5 x 3.0 x 1.2 cm. The external surface is tan-gray and smooth and glistening. There is a 1.3 x 1.0 cm cystic cavity. The entire specimen is submitted in C1 to C3.
- D. MESENTERIC MASS
Received fresh are three fragments of tan-pink soft tissue aggregating to 2 x 1.5 x 0.4 cm. Touch preparations are made. Tissue was sent for flow cytometry, tissue procurement, and snap frozen for possible future diagnostic studies. The rest of the tissue is submitted in cassette D1.

MICROSCOPIC DESCRIPTION:

Immunoperoxidase stains are performed on "A" and "B". In both no follicular dendritic cell meshworks are seen in CD21 stained tissue sections. The lymphoma is composed of medium (mainly) to large cells. No necrosis is seen. The lymphoma is positive for CD20, PAX5, CD23, CD43, BCL2, BCL6, BCL10 (weak cytoplasmic staining), and MUM1 and is otherwise negative for CD3, CD5, CD10, CD34, CD138, BCL1, and TdT. Ki-67 shows up to 60% nuclear proliferation index.

[page 2 of 2]
Flow cytometry, performed on tissue submitted from "D", shows a neoplastic B cell population (~60% of analyzed cells) that expresses CD45 (slightly weaker than T cells), HAL-DR, CD19, CD20 (dim), CD23, and surface kappa light chain immunoglobulin (dim) and lacks CD5 and CD10 expression. FISH analyses for bcl-1, bcl-2, bcl-6, c-myc, and malt-1 will be attempted on formalin-fixed paraffin embedded lymphoma tissue sections.

Source: NCI Genomic Data Commons file eb6942f7-b88f-4ea1-bd9e-3d681d198aa2 (TCGA-G8-6324.D42F1D12-1281-4822-8342-A9B14729432A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).